Somatic mutation profile of tumor specimen MP2PRT-PAVKLZ-TMP1-A (aliquot MP2PRT-PAVKLZ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVKLZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,003 days).
Specimen MP2PRT-PAVKLZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b5fe70-e120-4334-9b7d-78223b65db26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKLZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKLZ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/817b25f4-910f-4c61-b908-8a424805c6c1

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 91/231 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPB42 | c.631G>A p.V211M (on ENST00000441366 / NM_001114134.2; = p.V241M on NM_000119.3) | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752892136, COSV55749838; called by muse, varscan2
- ETV6 | c.305_306insGGAGGGG p.F102Lfs*12 | Frame Shift Ins (INS) | VAF 57/203 reads (28%) | catalogued as COSV67154527; called by mutect2, pindel, varscan2
- ITPR2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159482369, COSV67270866; called by muse, mutect2
- MAST1 | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1226893639, COSV52248290; called by muse, mutect2, varscan2
- P4HA3 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs775379703, COSV100525661; called by muse, mutect2, varscan2
- PRKCE | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60324757; called by muse, mutect2, varscan2
- CTAGE6 | c.647dup p.N216Kfs*9 | Frame Shift Ins (INS) | VAF 67/450 reads (15%) | called by mutect2, pindel, varscan2
- PMFBP1 | c.3003C>T p.I1001= (on ENST00000537465; = p.I996= on NM_031293.3) | Silent (SNP) | VAF 167/656 reads (25%) | catalogued as rs377243542; called by muse, mutect2, varscan2
- SEMA3B | c.399G>A p.T133= | Silent (SNP) | VAF 111/275 reads (40%) | catalogued as rs963384578, COSV60352459; called by muse, mutect2, varscan2
